Gene-level copy-number profile of tumor specimen TCGA-AA-3872-01A from TCGA case TCGA-AA-3872, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 45.6 years (16,651 days).
Specimen TCGA-AA-3872-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.5da9ed7f-29fd-4fa3-aed3-8e6b2d693e1b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3872-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df55c0c1-8b35-4e40-9d4b-a4deb39ed7d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,575; copy number 2: 24,681; copy number 3: 20,863; copy number 4: 8,213; copy number 5: 3,395; copy number 7: 30; copy number 42: 13; copy number 46: 8; copy number 57: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-3872-01): tumor purity 0.59, ploidy 2.86, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,487 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:100,550,724–104,256,094, 94 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:105,546,089–141,392,574, 405 genes, copy number 5–7 (broad region; genes not listed).
- chr9:134,527,182–138,203,325, 174 genes, copy number 5 (broad region; genes not listed).
- chr10:44,712–43,674,703, 730 genes, copy number 5 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 5 (broad region; genes not listed).
- chr14:22,086,407–22,518,871, 73 genes, copy number 5 (broad region; genes not listed).
- chr15:40,642,933–42,548,786, 78 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:63,544,247–65,229,967, 54 genes, copy number 5 (within-gene range 2–5): USP3-AS1, FBXL22, HERC1, AC073167.1, MIR422A, AC015914.2, DAPK2, AC015914.1, CIAO2A, SNX1, Y_RNA, SNX22, PPIB, CSNK1G1, AC087632.2, AC087632.1, PCLAF, TRIP4, Y_RNA, ZNF609, AC091231.1, GAPDHP61, AC090543.2, AC090543.1, Y_RNA, RNU6-549P, OAZ2, AC100830.3, AC100830.2, AC100830.1, RBPMS2, MIR1272, PIF1, PLEKHO2, AC069368.1, AC069368.2, ANKDD1A, AC103691.2, AC103691.1, SPG21, MTFMT, AC013553.2, SLC51B, AC013553.3, RASL12, KBTBD13, AC013553.4, UBAP1L, AC013553.1, PDCD7, CLPX, CILP, AC068213.1, RNU6-686P.
- chr15:71,096,952–74,696,292, 101 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:89,830,599–90,816,166, 50 genes, copy number 5 (within-gene range 2–5): AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1, CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585, BLM, SNORD18, AC124248.2.
- chr17:39,252,663–39,877,896, 21 genes, copy number 42–46 (within-gene range 1–46): FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr19:19,865,882–31,595,720, 275 genes, copy number 5 (broad region; genes not listed).
- chr19:36,604,817–37,614,179, 41 genes, copy number 57: ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571.

Autosomal genes at a single copy (total copy number 1): 2,575. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
